Somatic mutation profile of tumor specimen C3L-05870-57 (aliquot CPT0299480002) from CPTAC case C3L-05870, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 61.2 years (22,356 days).
Specimen C3L-05870-57: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f9b1241-e972-4596-82dd-22b0a84cd528.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05870-50 (Buccal Cell Normal), aliquot CPT0299470001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72181070-e7dd-4474-865c-d142b4267238

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HCFC2 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs978795089; called by muse, mutect2, varscan2
- HYDIN | c.8096G>A p.R2699H | Missense Mutation (SNP) | VAF 128/303 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs368332616; called by muse, varscan2
- ARHGAP22 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 125/285 reads (44%) | called by muse, mutect2, varscan2
- NR5A2 | c.1610A>T p.H537L (on ENST00000367362 / NM_205860.3; = p.H491L on NM_003822.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PSG1 | c.1077C>G p.N359K | Missense Mutation (SNP) | VAF 147/318 reads (46%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RRBP1 | c.3997C>A p.R1333S (on ENST00000377813 / NM_001365613.2; = p.R900S on NM_004587.3) | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SCARF2 | c.1858G>T p.V620L | Missense Mutation (SNP) | VAF 100/190 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TAF1 | c.2917G>T p.A973S (on ENST00000373790 / NM_138923.4; = p.A994S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLN1 | c.306C>T p.S102= | Silent (SNP) | VAF 88/230 reads (38%) | catalogued as COSV99535669; called by muse, mutect2, varscan2
- HERC1 | c.1956T>G p.T652= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as COSV71249814; called by muse, mutect2, varscan2
- ODF3L2 | c.34C>T p.L12= | Silent (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- XKR6 | c.798C>T p.S266= | Silent (SNP) | VAF 83/140 reads (59%) | catalogued as rs558779904; called by muse, mutect2, varscan2
